Gene-level copy-number profile of tumor specimen TCGA-77-6842-01A from TCGA case TCGA-77-6842, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.0 years (28,861 days).
Specimen TCGA-77-6842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cd8a429b-3b61-4563-9de9-ff9d9348e6f4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-6842-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17562639-1036-46b1-8228-7878f9a2aa1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,485; copy number 1: 2,098; copy number 2: 16,280; copy number 3: 15,065; copy number 4: 10,149; copy number 5: 9,051; copy number 6: 4,839; copy number 7: 234; copy number 8: 44; copy number 9: 99; copy number 10: 12; copy number 11: 44; copy number 13: 138; copy number 14: 562; copy number 16: 8; copy number 19: 25; copy number 21: 42; copy number 24: 24; copy number 25: 11; copy number 51: 1; copy number 98: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-6842-01A-11D-1943-01): tumor purity 0.48, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 200 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,003,618, 111 genes (broad region; genes not listed).
- chr9:19,789,179–22,824,213, 72 genes (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr9:23,500,691–25,089,151, 14 genes (within-gene range 0–5): AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15,146 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–125,823,315, 2,243 genes, copy number 6–19 (broad region; genes not listed).
- chr2:126,640,708–236,754,363, 1,804 genes, copy number 5–6 (broad region; genes not listed).
- chr3:99,598,064–124,726,325, 366 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:124,761,948–198,222,513, 1,349 genes, copy number 5 (within-gene range 4–6) (broad region; genes not listed).
- chr4:14,909,961–22,819,575, 78 genes, copy number 5 (broad region; genes not listed).
- chr4:29,748,757–39,032,922, 74 genes, copy number 5 (broad region; genes not listed).
- chr4:40,743,627–43,972,184, 51 genes, copy number 5: AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12.
- chr4:101,411,286–102,760,994, 17 genes, copy number 5–13 (within-gene range 2–13): BANK1, AC084277.1, RNU6-462P, MTND5P5, AP002075.1, SLC39A8, RN7SL728P, AC098487.1, AF213884.2, AF213884.3, NFKB1, MANBA, AF213884.1, LRRC37A15P, KRT8P46, AC018797.1, AC018797.2.
- chr5:58,198–45,895,970, 710 genes, copy number 9–14 (broad region; genes not listed).
- chr6:113,428,540–113,433,555, 1 gene, copy number 7: LINC02518.
- chr7:4,511,959–4,512,033, 1 gene, copy number 7: CYP3A54P.
- chr7:12,726,152–18,027,846, 55 genes, copy number 5 (within-gene range 4–5): AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:18,127,220–18,127,309, 1 gene, copy number 5: MIR1302-6.
- chr7:36,854,361–37,449,249, 1 gene, copy number 6 (within-gene range 4–6): ELMO1.
- chr7:36,997,796–37,117,185, 2 genes, copy number 6 (within-gene range 4–6): ELMO1-AS1, RPS17P13.
- chr7:38,655,205–38,932,394, 3 genes, copy number 7: KRT8P20, FAM183BP, VPS41.
- chr8:38,996,754–63,014,000, 355 genes, copy number 5–98 (within-gene range 2–98) (broad region; genes not listed).
- chr8:104,981,164–145,066,685, 590 genes, copy number 5–7 (broad region; genes not listed).
- chr9:14,475–6,727,438, 126 genes, copy number 6 (broad region; genes not listed).
- chr9:6,734,598–6,748,981, 2 genes, copy number 6: PRELID3BP11, SNRPEP2.
- chr9:7,786,105–17,503,923, 90 genes, copy number 5–6 (broad region; genes not listed).
- chr9:25,579,657–26,805,862, 9 genes, copy number 5: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1.
- chr9:28,863,626–29,826,711, 7 genes, copy number 7–13: MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:30,558,880–31,254,777, 10 genes, copy number 6: SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2.
- chr9:32,384,603–37,090,928, 204 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr11:70,014,858–81,556,425, 311 genes, copy number 5 (broad region; genes not listed).
- chr11:83,156,988–123,340,714, 797 genes, copy number 5 (broad region; genes not listed).
- chr11:123,381,440–123,381,512, 1 gene, copy number 5: MIR4493.
- chr11:124,800,424–124,834,487, 1 gene, copy number 5 (within-gene range 3–5): AP000866.1.
- chr11:124,865,432–129,538,114, 93 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–52,520,530, 1,230 genes, copy number 5–6 (broad region; genes not listed).
- chr12:54,058,254–54,122,235, 1 gene, copy number 5 (within-gene range 4–5): FLJ12825.
- chr12:54,081,736–128,244,573, 1,559 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:22,406,019–26,982,090, 22 genes, copy number 5: FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2, AC069061.1.
- chr17:55,264,960–73,092,712, 454 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:20,946,906–39,034,110, 271 genes, copy number 7–25 (broad region; genes not listed).
- chr20:87,250–47,188,844, 1,046 genes, copy number 5–6 (broad region; genes not listed).
- chr21:45,914,296–45,919,483, 1 gene, copy number 6: AJ239328.1.
- chr22:16,405,330–18,177,397, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:20,859,007–50,801,309, 1,121 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
